Somatic mutation profile of tumor specimen TCGA-5P-A9KF-01A (aliquot TCGA-5P-A9KF-01A-11D-A42J-10) from TCGA case TCGA-5P-A9KF, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 53.7 years (19,631 days).
Specimen TCGA-5P-A9KF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ecff5f28-c9fc-4f69-b59c-c603826ab6c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-5P-A9KF-10A (Blood Derived Normal), aliquot TCGA-5P-A9KF-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88b9509c-59ba-4ba6-aae0-4dd2b74a7361

The open-access MAF lists 73 somatic variants for this specimen: 61 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Frame Shift Del 13, Silent 11, Nonsense Mutation 5, In Frame Del 2, Splice Site 1, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 36/96 reads (38%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CNTNAP4 | c.1606C>G p.L536V | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as COSV56683310; called by muse, mutect2, varscan2
- CUBN | c.9080G>C p.G3027A | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64710032; called by muse, mutect2, varscan2
- FERMT2 | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 29/66 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772096782; called by muse, mutect2, varscan2
- GLG1 | c.1965G>C p.Q655H | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs752038762; called by muse, mutect2, varscan2
- ITGA9 | c.2302G>T p.E768* | Nonsense Mutation (SNP) | VAF 66/123 reads (54%) | catalogued as COSV53250788; called by muse, mutect2, varscan2
- KIAA0930 | c.170G>A p.R57Q (on ENST00000336156 / NM_001009880.2; = p.R62Q on NM_015264.2) | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.937); catalogued as rs547560699; called by muse, mutect2, varscan2
- MAGEA11 | c.149A>G p.Y50C | Missense Mutation (SNP) | VAF 124/156 reads (79%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs1433065632; called by muse, mutect2, varscan2
- MRPS21 | c.222C>G p.F74L | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as COSV100481654; called by muse, mutect2, varscan2
- OOEP | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.31); PolyPhen benign (0.009); catalogued as COSV64858970, COSV64859075; called by muse, mutect2, varscan2
- RBM17 | c.72A>T p.K24N | Missense Mutation (SNP) | VAF 49/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV65915164; called by muse, mutect2, varscan2
- TENM2 | c.6851G>T p.G2284V (on ENST00000518659 / NM_001122679.2; = p.G2045V on NM_001080428.3) | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69129975; called by muse, mutect2, varscan2
- ZBTB5 | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1453658964; called by muse, mutect2, varscan2
- ZDHHC1 | c.476del p.G159Vfs*62 | Frame Shift Del (DEL) | VAF 77/182 reads (42%) | catalogued as rs1349205343; called by mutect2, pindel, varscan2
- ABHD17C | c.398A>G p.Y133C | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.88); called by muse, varscan2
- AC090517.4 | c.810dup p.K271* | Frame Shift Ins (INS) | VAF 50/136 reads (37%) | called by mutect2, pindel, varscan2
- BBS10 | c.883A>T p.K295* | Nonsense Mutation (SNP) | VAF 16/36 reads (44%) | called by muse, mutect2, varscan2
- CDH7 | c.646C>A p.P216T | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CEP89 | c.811_812del p.L271Tfs*5 | Frame Shift Del (DEL) | VAF 20/61 reads (33%) | called by mutect2, pindel, varscan2
- CIT | c.200T>A p.L67Q | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CNTNAP1 | c.3304T>C p.S1102P | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CSMD2 | c.1907A>G p.D636G | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DARS2 | c.130T>A p.F44I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DOCK2 | c.453A>T p.K151N | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ERBB2 | c.3694del p.A1232Lfs*70 | Frame Shift Del (DEL) | VAF 370/1082 reads (34%) | called by mutect2, pindel, varscan2
- EVPL | c.1490G>A p.S497N | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- FARSA | c.790C>G p.Q264E | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FBH1 | c.672del p.F224Lfs*13 (on ENST00000362091 / NM_178150.3; = p.F275Lfs*13 on NM_032807.4) | Frame Shift Del (DEL) | VAF 30/61 reads (49%) | called by mutect2, pindel, varscan2
- FBXL14 | c.704T>C p.L235P | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FIBP | c.5C>A p.T2N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- FMNL2 | c.2774T>A p.L925Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2, varscan2
- GAPDH | c.188A>G p.E63G | Missense Mutation (SNP) | VAF 26/63 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.611); called by muse, mutect2, varscan2
- GGN | c.1267A>G p.N423D | Missense Mutation (SNP) | VAF 43/102 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- KIAA0930 | c.169C>G p.R57G (on ENST00000336156 / NM_001009880.2; = p.R62G on NM_015264.2) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MED12L | c.4211+1G>T p.X1404_splice | Splice Site (SNP) | VAF 59/78 reads (76%) | called by muse, mutect2, varscan2
- MRTFA | c.2787del p.S929Rfs*20 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | called by mutect2, pindel, varscan2
- MSH3 | c.2416G>T p.E806* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | called by muse, mutect2, varscan2
- MUC5B | c.5303C>A p.T1768K | Missense Mutation (SNP) | VAF 45/108 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- MYO5A | c.1636A>T p.K546* | Nonsense Mutation (SNP) | VAF 30/82 reads (37%) | called by muse, mutect2, varscan2
- NFE2 | c.827del p.N276Tfs*26 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- NRG2 | c.1091del p.G364Afs*44 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- P4HA2 | c.1466_1474del p.L489_S492delinsR | In Frame Del (DEL) | VAF 17/62 reads (27%) | called by mutect2, pindel, varscan2
- PARP11 | c.137A>G p.H46R | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PLAA | c.62T>A p.V21E | Missense Mutation (SNP) | VAF 63/190 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- PPIL4 | c.504C>G p.D168E | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- PTCD1 | c.1434G>T p.M478I | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RASGEF1A | c.554A>G p.K185R | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- RNASE2 | c.90_97del p.Q31Lfs*6 | Frame Shift Del (DEL) | VAF 42/107 reads (39%) | called by mutect2, pindel, varscan2
- RSF1 | c.744del p.E249Kfs*5 | Frame Shift Del (DEL) | VAF 14/53 reads (26%) | called by mutect2, pindel, varscan2
- SENP5 | c.637A>T p.I213F | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- SQLE | c.291G>C p.R97S | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- STOML2 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- SYN2 | c.738_747del p.I247Hfs*10 | Frame Shift Del (DEL) | VAF 24/98 reads (24%) | called by mutect2, pindel, varscan2
- SYNE2 | c.4532del p.N1511Ifs*3 | Frame Shift Del (DEL) | VAF 144/319 reads (45%) | called by mutect2, varscan2
- TMEM131L | c.1883del p.P628Lfs*6 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- TMEM184C | c.766_768del p.F256del | In Frame Del (DEL) | VAF 32/95 reads (34%) | called by mutect2, pindel, varscan2
- TRIM36 | c.1332_1341del p.K444Nfs*20 | Frame Shift Del (DEL) | VAF 19/72 reads (26%) | called by mutect2, pindel, varscan2
- TSSC4 | c.534T>A p.N178K | Missense Mutation (SNP) | VAF 55/123 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- UGT2B10 | c.1294A>C p.I432L | Missense Mutation (SNP) | VAF 140/341 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.414); called by muse, mutect2, varscan2
- ZMYM6 | c.1877C>T p.P626L | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF777 | c.544G>C p.E182Q | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ANGEL2 | c.966G>C p.L322= | Silent (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- DLG5 | c.2613A>G p.P871= | Silent (SNP) | VAF 19/43 reads (44%) | called by muse, mutect2, varscan2
- HLF | c.312T>C p.H104= | Silent (SNP) | VAF 74/120 reads (62%) | called by muse, mutect2, varscan2
- ITPRID2 | c.2418T>C p.S806= | Silent (SNP) | VAF 33/152 reads (22%) | called by muse, mutect2, varscan2
- OR4C15 | c.27C>A p.L9= | Silent (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- ROR2 | c.1914A>C p.R638= | Silent (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
- RTL3 | c.462G>A p.K154= | Silent (SNP) | VAF 27/33 reads (82%) | called by muse, mutect2, varscan2
- SHROOM3 | c.2064C>T p.Y688= | Silent (SNP) | VAF 18/43 reads (42%) | called by muse, mutect2, varscan2
- SLC19A2 | c.762G>A p.E254= | Silent (SNP) | VAF 34/99 reads (34%) | called by muse, mutect2, varscan2
- SMPD3 | c.684A>C p.P228= | Silent (SNP) | VAF 18/34 reads (53%) | called by muse, varscan2
- STXBP5L | c.3085C>A p.R1029= | Silent (SNP) | VAF 45/148 reads (30%) | called by muse, mutect2, varscan2
- SEPTIN9 | c.722-6592G>C | Intron (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
